Somatic mutation profile of tumor specimen MMRF_1705_1_BM_CD138pos (aliquot MMRF_1705_1_BM_CD138pos_T1_KBS5U_L05784) from MMRF case MMRF_1705, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.6 years (25,069 days).
Specimen MMRF_1705_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1667a316-1564-4c8f-96cf-ba7f1828c3bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1705_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1705_1_PB_WBC_C3_KBS5U_L05797; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7094f59-95c1-479e-9185-258cf479d500

The open-access MAF lists 64 somatic variants for this specimen: 29 protein-altering or splice-affecting, 7 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Intron 9, 3'UTR 9, Silent 7, 3'Flank 4, Splice Region 3, 5'Flank 3, Nonsense Mutation 2, 5'UTR 2, Frame Shift Del 2, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCAM | c.207C>T p.T69= | Splice Region (SNP) | VAF 6/64 reads (9%) | catalogued as rs1251047100; called by muse, mutect2
- CD14 | c.242A>G p.Q81R | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs780181417; called by muse, mutect2, varscan2
- EXD2 | c.1406A>G p.Y469C (on ENST00000312994 / NM_001193362.1; = p.Y344C on NM_018199.3) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs200113172; called by muse, mutect2, varscan2
- GABBR1 | c.1453T>G p.S485A | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.022); catalogued as rs989599729; called by muse, mutect2, varscan2
- H1-4 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.225); catalogued as rs548744758; called by muse, mutect2, varscan2
- IGLV3-1 | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 60/127 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs750241056; called by muse, mutect2, varscan2
- LRRTM4 | c.1368A>T p.Q456H | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.149); catalogued as COSV69142155; called by muse, mutect2, varscan2
- OR8I2 | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 102/228 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100136256; called by muse, varscan2
- ORC6 | c.323T>C p.I108T | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142697731; called by muse, mutect2, varscan2
- PHLDB2 | c.388C>G p.H130D | Missense Mutation (SNP) | VAF 58/151 reads (38%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.006); catalogued as COSV67313211; called by muse, mutect2, varscan2
- PKD1L1 | c.6667C>T p.R2223C | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.563); catalogued as rs757327591; called by muse, mutect2, varscan2
- PRRC2B | c.5272G>A p.E1758K | Missense Mutation (SNP) | VAF 87/165 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs755098511; called by muse, mutect2, varscan2
- ROS1 | c.1682C>T p.P561L | Missense Mutation (SNP) | VAF 67/139 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199766618, COSV63851597, COSV63858417; called by muse, mutect2, varscan2
- SCN10A | c.2659G>A p.A887T | Missense Mutation (SNP) | VAF 6/121 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs967347660, COSV71862738; called by muse, mutect2
- SLC22A23 | c.449G>A p.G150D | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.07); catalogued as rs1412243812; called by muse, mutect2, varscan2
- VWF | c.1027G>A p.V343M | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs746575545, COSV54629410; called by muse, mutect2, varscan2
- ZNF667 | c.1034del p.L345Rfs*33 | Frame Shift Del (DEL) | VAF 23/184 reads (13%) | catalogued as rs1319001453; called by mutect2, pindel, varscan2
- AJAP1 | c.61dup p.L21Pfs*22 | Frame Shift Ins (INS) | VAF 48/121 reads (40%) | called by mutect2, pindel, varscan2
- CDH5 | c.2207C>T p.S736F | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- DYRK4 | c.384G>T p.E128D | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- GMIP | c.821G>A p.C274Y | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- LCOR | c.458A>G p.Y153C | Missense Mutation (SNP) | VAF 64/192 reads (33%) | SIFT tolerated (0.32); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC32 | c.1432G>A p.G478R | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LYST | c.7227A>G p.E2409= | Splice Region (SNP) | VAF 29/185 reads (16%) | called by muse, mutect2, varscan2
- NBAS | c.2797C>G p.Q933E | Missense Mutation (SNP) | VAF 15/261 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); called by muse, mutect2
- NFKBIA | c.832C>T p.Q278* | Nonsense Mutation (SNP) | VAF 35/121 reads (29%) | called by muse, mutect2, varscan2
- NFKBIA | c.390_399del p.L131Afs*30 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | called by mutect2, pindel
- SLC6A19 | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 6/150 reads (4%) | called by muse, mutect2
- VPS13A | c.2904G>A p.K968= | Splice Region (SNP) | VAF 14/27 reads (52%) | called by muse, mutect2, varscan2
- CENPF | c.3777T>C p.S1259= | Silent (SNP) | VAF 104/224 reads (46%) | called by muse, mutect2, varscan2
- CNGA2 | c.1116C>A p.G372= | Silent (SNP) | VAF 48/55 reads (87%) | called by muse, mutect2, varscan2
- FREM2 | c.2451C>T p.T817= | Silent (SNP) | VAF 51/124 reads (41%) | catalogued as rs1284776931; called by muse, mutect2, varscan2
- KRT7 | c.12C>T p.H4= | Silent (SNP) | VAF 35/86 reads (41%) | called by muse, mutect2, varscan2
- NF1 | c.4569C>A p.S1523= (on ENST00000358273 / NM_001042492.3; = p.S1502= on NM_000267.3) | Silent (SNP) | VAF 73/187 reads (39%) | catalogued as CD1311347; called by muse, mutect2, varscan2
- VAX2 | c.780C>T p.A260= | Silent (SNP) | VAF 66/144 reads (46%) | catalogued as rs1553414645, COSV52267366; called by muse, mutect2, varscan2
- ZSCAN26 | c.1317G>A p.Q439= (on ENST00000623276 / NM_001111039.2; = p.Q305= on NM_152736.5) | Silent (SNP) | VAF 117/246 reads (48%) | called by muse, mutect2, varscan2
- AIFM3 | c.1758-115T>C | Intron (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- AKT2 | c.639+194G>A | Intron (SNP) | VAF 45/149 reads (30%) | catalogued as rs760739218; called by muse, mutect2, varscan2
- AMER1 | c.*255C>G | 3'UTR (SNP) | VAF 17/19 reads (89%) | called by muse, mutect2, varscan2
- API5 | c.231+114G>A | Intron (SNP) | VAF 7/18 reads (39%) | called by muse, varscan2
- BCL7A | chr12:122021401 G>A | 5'Flank (SNP) | VAF 39/104 reads (38%) | catalogued as rs547304687, COSV55852870; called by muse, mutect2, varscan2
- C17orf107 | c.*1371G>T | 3'UTR (SNP) | VAF 6/64 reads (9%) | catalogued as rs780394697; called by muse, mutect2, varscan2
- CD244 | chr1:160831106 G>A | 3'Flank (SNP) | VAF 44/108 reads (41%) | called by muse, mutect2, varscan2
- CEP170P1 | n.1977C>T | RNA (SNP) | VAF 90/169 reads (53%) | called by muse, mutect2, varscan2
- CGREF1 | chr2:27099604 G>A | 3'Flank (SNP) | VAF 71/156 reads (46%) | catalogued as rs750612355; called by muse, mutect2, varscan2
- CMTM3 | c.-13C>T | 5'UTR (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2
- COBL | c.1096+20696T>G | Intron (SNP) | VAF 4/56 reads (7%) | called by muse, mutect2
- COL5A1 | c.*2040G>A | 3'UTR (SNP) | VAF 9/83 reads (11%) | catalogued as rs924886427; called by muse, mutect2, varscan2
- FEZ1 | chr11:125499263 T>C | 5'Flank (SNP) | VAF 8/133 reads (6%) | called by muse, mutect2
- KIF1B | c.2115+11131G>A | Intron (SNP) | VAF 21/66 reads (32%) | catalogued as rs879074059; called by muse, mutect2, varscan2
- MACC1 | chr7:20140176 A>G | 3'Flank (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2
- MIR5195 | chr14:106851275 T>A | 5'Flank (SNP) | VAF 96/132 reads (73%) | catalogued as rs542998783; called by muse, mutect2, varscan2
- NFE2L3 | c.*857G>A | 3'UTR (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- PPFIA4 | c.*1605G>A | 3'UTR (SNP) | VAF 15/110 reads (14%) | called by muse, mutect2, varscan2
- PTPRT | c.*2691A>G | 3'UTR (SNP) | VAF 36/85 reads (42%) | called by muse, mutect2, varscan2
- RAB11FIP4 | c.*5584T>A | 3'UTR (SNP) | VAF 20/114 reads (18%) | called by muse, mutect2, varscan2
- RIPPLY2 | c.240-67T>C | Intron (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- SLC1A7 | c.*596T>C | 3'UTR (SNP) | VAF 9/138 reads (7%) | called by muse, mutect2
- SMARCAD1 | c.1282-100A>C | Intron (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- SNX13 | c.440+74A>C | Intron (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- SRSF3 | c.*867T>C | 3'UTR (SNP) | VAF 9/96 reads (9%) | called by muse, mutect2
- TRIQK | chr8:92883924 A>G | 3'Flank (SNP) | VAF 25/66 reads (38%) | called by muse, mutect2, varscan2
- UBE2D2 | c.-241G>A | 5'UTR (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2, varscan2
- ZDHHC14 | c.704-22A>T | Intron (SNP) | VAF 28/185 reads (15%) | called by muse, mutect2, varscan2
